MMRF case MMRF_2728 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b4818d6b-3197-46f5-8088-fcfcb4c29e44

Demographics
Sex at birth: male; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: I; Days to last known disease status: 154 days; Days to last follow up: 154 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -8, day 154.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.58 mmol/L.
- Lactate Dehydrogenase 5.63 µkat/L.
- M Protein 3.4 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 335 mg/dL.
- Platelets 365 ×10⁹/L.
- Hemoglobin 7.75 mmol/L.
- Creatinine 40.7 µmol/L.
- Absolute Neutrophil 3.67 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL.
- Albumin 39 g/L.
- Beta 2 Microglobulin 0.3 µg/mL.

Other clinical attributes
- Day -8: Weight: 60 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_2728_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2728_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
